CCDI case PBCTTK — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/c62962fb-7b28-48c7-971c-f31b98393c96

Demographics
Sex at birth: male; Race: black or african american.

Diagnoses (1)
1. Neoplasm, uncertain whether benign or malignant: ICD-O-3 morphology code: 8000/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.6 years (5,316 days).

Biospecimens (3 samples)
- Sample 0DZB1J: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DZB1S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
- Sample 0DZB2A: Tissue type: Tumor; Specimen type: Solid Tissue.
